Surgical pathology report (de-identified scan), TCGA case TCGA-GS-A9TW, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Fundacio Clinic per a la Recerca Biomedica, specimen TCGA-GS-A9TW-01A (Primary Tumor).

AXILLAR LYMPH NODE :

We receive three tissue fragments of pinky color, the biggest of 2,7x2x0,8 cm, and the smallest of 1,5x1x1 cm.

AXILLAR LYMPH NODE, EXCISION:

- PRIMARY MEDIASTINAL DIFFUSE LARGE B CELL LYMPHOMA

The architecture of the lymph node shows a large cell lymphoma with a diffuse growth pattern, with cells of an anaplastic morphology and sclerosis. The immunophenotypic study shows that the neoplastic cells are positive for CD20, CD79a, BOB1, OCT2, BCL2 and BCL6 with moderate and heterogeneous expression of CD30, and are negative for CD10, CD3, CD5 and CD15. In situ hybridization for the RNA of the Epstein- Barr virus (EBER) is negative. The Ki-67 proliferative index is 90%.

IOD-0-3
Lymphoma, diffuse large B cell NOS
968013
Site Lymph node, axilla
C773
JCO 3/31/14

Source: NCI Genomic Data Commons file b96d89a1-bd12-43e3-898a-2ce59dc747e0 (TCGA-GS-A9TW.2D2E6687-CD36-42F1-A091-7B249A2FAFF6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).